FM case AD9324 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/87ad296b-1335-4943-b507-46702defce40

Female, 53.3 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the head, face or neck; specimen biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
